Somatic mutation profile of tumor specimen TCGA-EM-A4FV-01A (aliquot TCGA-EM-A4FV-01A-11D-A257-08) from TCGA case TCGA-EM-A4FV, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 64.7 years (23,627 days).
Specimen TCGA-EM-A4FV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0c34107e-2d25-4114-8c5e-fef2b2b988d5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EM-A4FV-10A (Blood Derived Normal), aliquot TCGA-EM-A4FV-10A-01D-A25A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c3451788-93b7-4086-b20d-eaa5013fecd5

The open-access MAF lists 23 somatic variants for this specimen: 16 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 14, Silent 7, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2
- DHCR24 | c.281G>A p.R94H | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs387906939, CM114959, COSV64874503; ClinVar: pathogenic; called by muse, mutect2, varscan2
- EIF1AX | c.338-1G>C p.X113_splice | Splice Site (SNP) | VAF 7/39 reads (18%) | hotspot (GDC flag); catalogued as COSV65450922, COSV65451214, COSV65451406; called by muse, mutect2
- KRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 9/34 reads (26%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.083); catalogued as rs121913238, COSV55502066, COSV55502677; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CYTH1 | c.401A>T p.H134L | Missense Mutation (SNP) | VAF 6/93 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.169); catalogued as COSV63120323; called by muse, mutect2
- FBXL2 | c.895A>G p.I299V | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.009); catalogued as rs1198018362, COSV52138594; called by muse, mutect2, varscan2
- FMR1 | c.1541C>T p.S514L | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as COSV54423714; called by muse, mutect2, varscan2
- IFRD1 | c.1218G>A p.M406I | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.49); PolyPhen benign (0.03); catalogued as COSV50044088; called by muse, mutect2, varscan2
- MCOLN1 | c.1436C>T p.A479V | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.326); catalogued as COSV51175378; called by muse, mutect2
- MRS2 | c.818G>C p.W273S | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.843); catalogued as COSV51234353; called by muse, mutect2, varscan2
- PROS1 | c.1711C>A p.Q571K | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.125); catalogued as CM164013, COSV67775290; called by muse, mutect2, varscan2
- RRAGD | c.961C>A p.L321I | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.858); catalogued as COSV63269033; called by muse, mutect2, varscan2
- SLITRK6 | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs771630878, COSV68390125; called by muse, mutect2, varscan2
- SRSF12 | c.482C>G p.S161C | Missense Mutation (SNP) | VAF 47/173 reads (27%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.984); catalogued as COSV71683673; called by muse, mutect2, varscan2
- ZNF467 | c.1564C>T p.R522C | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs746749618, COSV57372980; called by muse, mutect2, varscan2
- GSTO2 | c.99del p.Y34Ifs*23 | Frame Shift Del (DEL) | VAF 11/56 reads (20%) | called by mutect2, pindel, varscan2
- ANAPC7 | c.1668G>A p.E556= | Silent (SNP) | VAF 3/32 reads (9%) | catalogued as COSV71443822; called by muse, mutect2
- GABBR1 | c.855A>C p.R285= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as COSV63542411, COSV63543353; called by muse, mutect2, varscan2
- GTPBP4 | c.837C>T p.F279= | Silent (SNP) | VAF 6/81 reads (7%) | catalogued as rs1180805948, COSV62550811; called by muse, mutect2
- KRAS | c.180T>A p.G60= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as rs397517037, COSV55499291, COSV55523567, COSV99782811; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OR8D1 | c.627G>A p.V209= | Silent (SNP) | VAF 5/37 reads (14%) | catalogued as COSV63442189; called by muse, mutect2, varscan2
- VN1R2 | c.417C>T p.I139= | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as rs778685542, COSV59038177; called by muse, mutect2, varscan2
- ZNF362 | c.363C>T p.S121= | Silent (SNP) | VAF 13/46 reads (28%) | catalogued as rs770133468, COSV65031413; called by muse, mutect2, varscan2
